Somatic mutation profile of tumor specimen MMRF_2795_1_BM_CD138pos (aliquot MMRF_2795_1_BM_CD138pos_T1_KHS5U_L15736) from MMRF case MMRF_2795, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.3 years (21,279 days).
Specimen MMRF_2795_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2544f5f0-0d84-48ae-a5ed-3f6562faec15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2795_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2795_1_PB_WBC_C3_KHS5U_L15780; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35d35d83-7ece-49bd-a0c9-8dc2162fc188

The open-access MAF lists 90 somatic variants for this specimen: 43 protein-altering or splice-affecting, 8 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 21, Intron 8, Silent 8, 5'UTR 5, RNA 4, Splice Site 3, In Frame Del 1, 3'Flank 1, Splice Region 1, Frame Shift Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 33/135 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- AP2A1 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 84/400 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as rs1467549674; called by muse, mutect2, varscan2
- CCDC78 | c.492+5G>A | Splice Region (SNP) | VAF 43/116 reads (37%) | catalogued as rs748906891; called by muse, mutect2, varscan2
- GAS2L3 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 97/266 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs146021257; called by muse, mutect2, varscan2
- HERC1 | c.9509G>A p.R3170H | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs369547448; called by muse, mutect2, varscan2
- IGHV2-70 | c.75G>C p.E25D | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs181122105; called by muse, varscan2
- KRT1 | c.1642G>A p.G548S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.937); catalogued as rs775570636, COSV99358900; called by muse, mutect2, varscan2
- MAPK6 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs1200298736, COSV55930548; called by muse, mutect2, varscan2
- MARF1 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100706594; called by muse, mutect2, varscan2
- MYBPC2 | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 79/270 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as rs759169585; called by muse, mutect2, varscan2
- ROBO1 | c.3443G>A p.G1148E | Missense Mutation (SNP) | VAF 75/230 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as rs779942722; called by muse, mutect2, varscan2
- RUNDC3B | c.558G>A p.M186I | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as rs1337472215; called by muse, mutect2, varscan2
- SMG1 | c.10651C>G p.Q3551E | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.351); catalogued as COSV101246142, COSV67169170; called by muse, mutect2, varscan2
- TMEM131L | c.4350C>G p.C1450W | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99547220; called by muse, mutect2, varscan2
- TRIM44 | c.305A>G p.E102G | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs918060256; called by muse, mutect2, varscan2
- VCAM1 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as rs369761581; called by muse, mutect2, varscan2
- AC020907.6 | c.147_153del p.C49Wfs*7 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | called by mutect2, pindel, varscan2
- ASTN1 | c.3518A>C p.Q1173P | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CAPN6 | c.101C>G p.P34R | Missense Mutation (SNP) | VAF 69/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CHKA | c.969A>T p.K323N | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLSTN3 | c.887A>G p.D296G | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COX6B2 | c.87_89dup p.R30dup | In Frame Ins (INS) | VAF 6/50 reads (12%) | called by mutect2, pindel, varscan2
- CPD | c.3740A>G p.Y1247C | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- EPS8L2 | c.1663G>A p.G555S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2
- F10 | c.953C>A p.T318N | Missense Mutation (SNP) | VAF 55/361 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAT3 | c.5446G>T p.V1816L | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- HOXA4 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- IGHV1-3 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.213); called by muse, varscan2
- IGHV1-3 | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.57); called by muse, varscan2
- IGKV2-24 | c.328G>C p.V110L | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- IGLV3-1 | c.47-1_47delinsT p.X16_splice | Splice Site (DEL) | VAF 46/173 reads (27%) | called by pindel, varscan2*
- INPP5D | c.2633C>T p.P878L (on ENST00000445964 / NM_001017915.3; = p.P877L on NM_005541.5) | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- IPO13 | c.1604T>G p.L535R | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- MED16 | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- P2RX3 | c.706-2del p.X236_splice | Splice Site (DEL) | VAF 23/91 reads (25%) | called by mutect2, pindel, varscan2
- PDZD4 | c.1052A>T p.D351V | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- RASSF10 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RFT1 | c.1294A>C p.I432L | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPL7A | c.121A>T p.I41F | Missense Mutation (SNP) | VAF 142/277 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SNX13 | c.13-1G>A p.X5_splice | Splice Site (SNP) | VAF 46/165 reads (28%) | called by muse, mutect2, varscan2
- TMEM262 | c.330G>C p.E110D (on ENST00000530719 / NM_001282448.1; = p.V98L on NM_001242631.2) | Missense Mutation (SNP) | VAF 7/197 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.398); called by muse, mutect2
- ZBED6 | c.634_642del p.N212_S214del | In Frame Del (DEL) | VAF 40/162 reads (25%) | called by mutect2, varscan2
- ZNF821 | c.809G>A p.R270Q (on ENST00000425432 / NM_001376297.1; = p.R228Q on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DUSP2 | c.382C>T p.L128= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as rs1420545239, COSV56620626; called by muse, mutect2, varscan2
- IGHV1-3 | c.66G>A p.Q22= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as rs782476605; called by muse, varscan2
- IGHV2-70 | c.297G>C p.V99= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as rs138072391; called by muse, varscan2
- IGKV2-24 | c.327G>A p.G109= | Silent (SNP) | VAF 38/67 reads (57%) | catalogued as rs112678521; called by muse, mutect2, varscan2
- MYO5A | c.4245G>A p.L1415= | Silent (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- NACC2 | c.384C>T p.C128= | Silent (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- SMCHD1 | c.1635T>A p.I545= | Silent (SNP) | VAF 18/46 reads (39%) | called by muse, varscan2
- TGM6 | c.123G>T p.T41= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV52477170, COSV52483499; called by muse, mutect2, varscan2
- AC022148.1 | n.13G>A | RNA (SNP) | VAF 35/98 reads (36%) | catalogued as rs960343985; called by muse, mutect2, varscan2
- ACSL6 | c.*51G>T | 3'UTR (SNP) | VAF 38/195 reads (19%) | called by muse, mutect2, varscan2
- ADAM12 | c.*1826A>T | 3'UTR (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- AKR1D1 | c.*87A>T | 3'UTR (SNP) | VAF 78/335 reads (23%) | called by muse, mutect2, varscan2
- ALDOC | c.-12-69T>C | Intron (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- ATG3 | c.-365G>A | 5'UTR (SNP) | VAF 27/75 reads (36%) | called by muse, mutect2, varscan2
- ATP8A1 | c.*2040C>T | 3'UTR (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- AUNIP | c.*359T>G | 3'UTR (SNP) | VAF 10/24 reads (42%) | catalogued as rs1553123188, COSV65353221; called by mutect2, varscan2
- BCCIP | c.850+286A>T | Intron (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- CEP170 | c.1843+302T>A | Intron (SNP) | VAF 6/18 reads (33%) | catalogued as rs2789178; called by muse, mutect2
- COL20A1 | c.2806+20G>A | Intron (SNP) | VAF 24/66 reads (36%) | catalogued as rs373476372; called by muse, mutect2
- COL4A5 | c.4803+64C>A | Intron (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2
- CPNE3 | c.*2797T>C | 3'UTR (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- DIPK2A | c.*586_*587insG | 3'UTR (INS) | VAF 4/43 reads (9%) | catalogued as rs891476340; called by pindel, varscan2
- DKC1 | c.*218G>C | 3'UTR (SNP) | VAF 30/97 reads (31%) | called by muse, mutect2, varscan2
- EPB42 | c.*62G>A | 3'UTR (SNP) | VAF 85/318 reads (27%) | called by muse, mutect2, varscan2
- GABRE | c.*913G>A | 3'UTR (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- IGKV3-20 | c.-18T>G | 5'UTR (SNP) | VAF 19/29 reads (66%) | catalogued as rs778229813; called by muse, mutect2, varscan2
- IKZF2 | c.-119-20C>T | Intron (SNP) | VAF 48/164 reads (29%) | catalogued as rs1479223638; called by muse, mutect2, varscan2
- INSYN2A | c.*354C>T | 3'UTR (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- LCN6 | chr9:136743031 C>T | 3'Flank (SNP) | VAF 6/32 reads (19%) | catalogued as rs1013767736; called by muse, mutect2, varscan2
- LINC00894 | n.2018C>T | RNA (SNP) | VAF 44/115 reads (38%) | catalogued as rs1434337939; called by muse, mutect2, varscan2
- LTB | c.163-93A>G | Intron (SNP) | VAF 114/303 reads (38%) | called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.715C>T | RNA (SNP) | VAF 48/155 reads (31%) | catalogued as rs782500275; called by muse, mutect2, varscan2
- MOGS | c.-1G>A | 5'UTR (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2, varscan2
- NLE1 | c.*1179C>T | 3'UTR (SNP) | VAF 9/15 reads (60%) | catalogued as rs1159423204; called by muse, varscan2
- PAWR | c.*3818C>A | 3'UTR (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- PEG3 | c.*1551T>G | 3'UTR (SNP) | VAF 29/49 reads (59%) | called by muse, mutect2, varscan2
- PHETA1 | c.*683C>A | 3'UTR (SNP) | VAF 31/102 reads (30%) | called by muse, mutect2, varscan2
- PRKACB | c.-206C>T | 5'UTR (SNP) | VAF 4/47 reads (9%) | catalogued as rs1557887994, COSV65771414; called by muse, mutect2
- RYR2 | c.14151+125G>A | Intron (SNP) | VAF 7/21 reads (33%) | called by mutect2, varscan2
- SEMA4D | c.*457T>C | 3'UTR (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- SKA3 | c.*1037T>C | 3'UTR (SNP) | VAF 31/89 reads (35%) | called by muse, mutect2, varscan2
- SLC6A14 | c.*1932G>T | 3'UTR (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- SMC4 | c.*1054A>T | 3'UTR (SNP) | VAF 40/80 reads (50%) | catalogued as rs1001670299; called by muse, mutect2, varscan2
- TMOD2 | c.*7656T>C | 3'UTR (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2, varscan2
- TNRC18P3 | n.1416C>T | RNA (SNP) | VAF 2/18 reads (11%) | catalogued as rs868959128; called by muse, mutect2
- ZNF343 | c.-30C>T | 5'UTR (SNP) | VAF 33/112 reads (29%) | called by muse, mutect2, varscan2
- ZNF419 | c.*240G>A | 3'UTR (SNP) | VAF 42/79 reads (53%) | catalogued as rs1182743464; called by muse, mutect2, varscan2
